Somatic mutation profile of tumor specimen BA2052D (aliquot aq-BA2052D) from BEATAML1.0 case 2412, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.4 years (26,063 days).
Specimen BA2052D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39f92dec-207c-4ca0-9c48-4049a6d0056a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2896D (Solid Tissue Normal), aliquot aq-BA2896D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc3145de-c1b6-48df-9cd0-721e51143e9c

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 19, Silent 8, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4111C>T p.Q1371* (on ENST00000378444 / NM_001123385.2; = p.Q1337* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 60/89 reads (67%) | catalogued as rs863224850, COSV60705391; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTCF | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs968244943, COSV50461455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COX18 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs773843778; called by muse, mutect2, varscan2
- CUL5 | c.1933C>T p.R645W | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs1380916130; called by muse, mutect2, varscan2
- H2AW | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 52/177 reads (29%) | catalogued as rs1201587948; called by muse, mutect2, varscan2
- INCENP | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs746543284, COSV53914105; called by muse, mutect2, varscan2
- IRX5 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs1182419728; called by muse, mutect2, varscan2
- KRT14 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs762702328, COSV51420680; called by muse, mutect2, varscan2
- NLRP8 | c.1752G>T p.K584N | Missense Mutation (SNP) | VAF 94/210 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52593461; called by muse, mutect2, varscan2
- PC | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 115/265 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); catalogued as rs776465359, COSV100852342; called by muse, mutect2, varscan2
- PLEKHG2 | c.2689G>C p.V897L | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1471636262; called by muse, varscan2
- RET | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.585); catalogued as COSV60711598; called by mutect2, varscan2
- WDPCP | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs753480088, COSV55414635; called by muse, varscan2
- ZMYND8 | c.1061G>T p.R354L (on ENST00000311275 / NM_001363741.2; = p.R374L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs931125721, COSV104369369; called by muse, mutect2, varscan2
- ADH1B | c.845G>T p.C282F | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2
- B3GALT1 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- BMPER | c.2016C>A p.H672Q | Missense Mutation (SNP) | VAF 97/176 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- C1R | c.70G>T p.A24S (on ENST00000536053 / NM_001354346.2; = p.A10S on NM_001733.7) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.028); called by muse, mutect2
- DRD2 | c.13A>T p.N5Y | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- MICAL2 | c.5417C>T p.A1806V | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIEZO2 | c.4753G>T p.A1585S | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- HERC2 | c.7458C>G p.S2486= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV55324781; called by muse, mutect2, varscan2
- ICAM5 | c.1672C>A p.R558= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV55748870; called by muse, mutect2
- MEIOB | c.612G>A p.S204= | Silent (SNP) | VAF 43/138 reads (31%) | catalogued as rs760667884, COSV100379916; called by muse, mutect2, varscan2
- NR0B1 | c.741G>T p.A247= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV100973422; called by muse, mutect2
- NSUN3 | c.171C>T p.N57= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- RTN2 | c.1050C>T p.Y350= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs1378668120; called by muse, mutect2, varscan2
- SALL3 | c.2691C>T p.S897= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs755579014, COSV101609935, COSV73306272; called by muse, mutect2, varscan2
- SGPP1 | c.186G>A p.A62= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs1364267653; called by muse, mutect2, varscan2
